Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4866, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4866-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/Add [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA - CZ - 4866

PATHOLOGIC DIAGNOSIS:

- A. SPECIMEN LABELED "RIGHT KIDNEY":
RENAL CELL CARCINOMA, CLEAR CELL TYPE (3.3 cm) Fuhrman grade 3 (of 4).
Tumor does not invade through the renal capsule.
Lymphovascular invasion is present.
Vascular and ureteral margins are negative for tumor.
No adrenal gland present.

AJCC Classification (6th Edition): T1 NX MX.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

CLINICAL DATA:

History: None given.
Operation: Right nephrectomy.
Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1) right kidney.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patients name, unit number, and "#1 - right kidney", and consists of a 207 gram right nephrectomy, measuring 11.0 x 6.0 x 3.2 cm, including a single kidney and loosely attached perirenal adipose tissue. The renal vein measures 0.3 cm in length x 0.4 cm in diameter, renal artery measures 0.5 cm in length x 0.3 cm in diameter, and the ureter measures 7.5 cm in length x 0.2 cm in diameter. There is a bulging mass at the anterior surface of the inferior pole of the kidney, measuring 3.3 x 2.5 x 2.3 cm. Sectioning of the mass reveals that it is heterogeneous in appearance, and is yellow/brown in color and focally hemorrhagic. The mass abuts the capsule and pelvis, but there is no invasion through these structures. The renal vein is uninvolved by the tumor. The remainder of the parenchyma is tan/red with distinct corticomedullary junction. Representative sections of tumor and normal kidney are submitted to tissue banking. A representative section of tumor is sent for cytogenetics and immunofluorescence. Representative sections of normal kidney are sent for electron microscopy and immunofluorescence analysis.

Micro A1: vascular and ureteral margins, 3 frags, [REDACTED]
Micro A2: quick fix tumor, 1 frag, [REDACTED]
Micro A3+A4: representative sections of tumor with respect to capsule and inked perirenal fat, 1 frag per cassette, [REDACTED]
Micro A5: tumor with respect to hilum, 1 frag, [REDACTED]
Micro A6: tumor and adjacent normal kidney, 1 frag, [REDACTED]
Micro A7: tumor with respect to renal calyx, 1 frag, [REDACTED]
Micro A8: normal kidney, 1 frag, [REDACTED]

The adipose tissue surrounding the kidney is thinly sectioned, and no lymph nodes or adrenal gland are identified.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es)

[page 2 of 4]
[REDACTED]

Pathology Report

related thereto.

[REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

RIGHT KIDNEY, NEPHRECTOMY:

MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST LIKELY AGE-RELATED (SEE NOTE)

GIVEN THE HISTORY OF PERSISTENT MICROSCOPIC HEMATURIA, ASSESSMENT OF GLOMERULAR BASEMENT MEMBRANE THICKNESS WILL BE PERFORMED AND REPORTED IN AN ADDENDUM (SEE NOTE)

NOTE:

The kidney parenchyma sample examined shows minimal chronic changes, within the expected range for a [REDACTED] old woman. There is a mild degree of focal global glomerulosclerosis (5.1% of glomeruli), minimal tubular atrophy and interstitial fibrosis (less than 5% of the parenchyma), and a mild to focally moderate degree of vascular sclerosis.

Electron microscopy will be performed to assess morphometrically the glomerular basement membrane thickness given the long-standing history of asymptomatic microscopic hematuria. The findings will be reported in an addendum.

The kidney parenchyma has been reviewed by Dr. [REDACTED] Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A8) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 215 glomeruli present, of which 11 (5.1%) are globally sclerosed. The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. Rare distal tubules contain PAS-positive hyaline casts. Several tubules show cystic dilatation and most contained pigmented granular material within the lumen. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a mild to focally moderate degree of sclerosis with focal hyaline degeneration.

[REDACTED]

ADDENDUM (#2)

RIGHT KIDNEY, NEPHRECTOMY:

ULTRASTRUCTURAL EVALUATION PERFORMED FOR HISTORY OF PERSISTENT MICROSCOPIC HEMATURIA REVEALS marginally thin glomerular basement membranes, suggestive of an inherited abnormality of basement membrane collagens (SEE NOTE)

SEE PRIOR ADDENDUM FOR ADDITIONAL FINDINGS

NOTE:

The corrected mean harmonic thickness of the glomerular capillary wall basement membrane was 251 nm, which is below the lower normal limit of 264 nm [REDACTED]

[page 3 of 4]
Pathology Report

These authors estimated the range of normal values from the data of [REDACTED], as the mean (350 nm) plus and minus two standard deviations (normal thickness values should fall between 264 and 436 nm). Thin glomerular basement membranes are often a phenotypic expression of an inherited abnormality in basement membrane collagens, and often manifest as persistent microscopic hematuria in affected patients and family members. In women, thin basement membranes can be seen in carriers of the X-linked Alport syndrome gene, patients with autosomal recessive hereditary nephritis, and patients with so-called benign hematuria or thin glomerular basement membrane disease. In males, this phenotype can also be seen in early stages of the Alport syndrome and, similar to the situation in women, in patients with so-called thin glomerular basement membrane disease and autosomal recessive hereditary nephritis. Thin basement membrane disease has been associated with heterozygous defects in the gene for alpha 4 collagen IV and familial benign hematuria; persistent hematuria is inherited as a dominant trait, progressive renal failure is inherited as recessive feature. The prevalence of this genetic defect in the general population has been reported to be high; the estimates lie in the 2-9% range. Homozygous defects in alpha 4 or alpha 3 collagen IV have been reported to be associated with autosomal recessive forms of hereditary nephritis; patients with this type of defect have the strongest family history of hematuria, and in general, both parents and all offspring can be expected to have persistent microscopic hematuria. No features suggestive of the classic Alport syndrome (splitting, lamination, and thickening of the glomerular basement membranes) could be identified in this patient.

REFERENCES:

ELECTRON MICROSCOPY REPORT [REDACTED]:

Blocks: 8. Blocks examined: 4 thick sections, 1 thin section.

The tissue examined at the ultrastructural level contains four glomeruli. Visceral epithelial cell foot processes are preserved. There is rare vacuolization of the visceral epithelial cells. No deposits are seen, and there is no significant mesangial expansion. Some capillaries show erythrocyte congestion but no substructures are seen in the erythrocyte cytoplasm. The endothelium is largely unremarkable. The glomerular basement membranes appear thin; measurement of the basement membrane thickness was performed by the method of orthogonal intercepts. A total of 94 sites were measured on the electron micrographs. The corrected mean arithmetic thickness of the glomerular basement membranes was 241.37 nm, and the corrected mean harmonic thickness was 250.51 nm. Tubules are well preserved, with some large vacuoles in the epithelial cells focally. There is a mild degree of arterial and arteriolar sclerosis with focal hyalinosis.

[page 4 of 4]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist: [REDACTED]

Report Status: F [REDACTED]

KARYOTYPE: 70,XX,del(3)(p1?2)[1]

METAPHASES COUNTED: 1

ANALYZED: 1

SCORED: 0

BANDING: GTG

INTERPRETATION:

Only 1 metaphase cell was obtained and analyzed from this specimen and contained a deletion of the short arm of chromosome 3, a characteristic finding in renal cell carcinoma, clear cell type. This limited/incomplete study may not rule out mosaicism at a level that is standard for such an analysis.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

[REDACTED]

Source: NCI Genomic Data Commons file 8fe110c5-d823-4ad1-adad-0dbe27530e42 (TCGA-CZ-4866.A317B781-0925-46DC-A779-FB2C9A5920D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).